MMRF case MMRF_1189 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/994fda2d-17af-451a-954a-95410558319b

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 65 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 65.2 years (23,830 days); ISS stage: I; Days to last known disease status: 1,627 days (4.5 years); Days to last follow up: 1,627 days (4.5 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 11 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 4 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 8 days; Days to treatment end: 11 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 228 days; Days to treatment end: 228 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 697 days (1.9 years); Days to treatment end: 1,271 days (3.5 years).
   Treatment given: Therapeutic agents: Other; Regimen or line of therapy: Third line of therapy; Days to treatment start: 1,717 days (4.7 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 1,627.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -11 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 572 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.07 mg/dL; Immunoglobulin G 4.09 g/L; Immunoglobulin A 0.28 g/L; Immunoglobulin M 0.11 g/L; Beta 2 Microglobulin 2.93 µg/mL; Lactate Dehydrogenase 2.38 µkat/L; Hemoglobin 8.87 mmol/L; Leukocytes 11.6 ×10⁹/L; Absolute Neutrophil 6.98 ×10⁹/L; Platelets 297 ×10⁹/L; Creatinine 67.2 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 3.4 mmol/L; Albumin 43 g/L; Total Protein 7.1 g/dL; Glucose 10.4 mmol/L.
- Day 79: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.58 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.1 mg/dL; Immunoglobulin G 3.48 g/L; Immunoglobulin A 0.29 g/L; Immunoglobulin M 0.37 g/L; Lactate Dehydrogenase 3.75 µkat/L; Hemoglobin 8.31 mmol/L; Leukocytes 12.4 ×10⁹/L; Absolute Neutrophil 8.89 ×10⁹/L; Platelets 226 ×10⁹/L; Creatinine 67.2 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 1.8 mmol/L; Albumin 39 g/L; Total Protein 5.9 g/dL; Glucose 8.03 mmol/L.
- Day 186: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.82 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.1 mg/dL; Immunoglobulin G 5.67 g/L; Immunoglobulin A 0.91 g/L; Immunoglobulin M 0.48 g/L; Lactate Dehydrogenase 2.42 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 8.1 ×10⁹/L; Absolute Neutrophil 5.5 ×10⁹/L; Platelets 289 ×10⁹/L; Creatinine 69 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.28 mmol/L; Albumin 40 g/L; Total Protein 6.4 g/dL; Glucose 6.33 mmol/L.
- Day 277 (ECOG 0): M Protein 0 g/dL; Immunoglobulin G 5.67 g/L; Immunoglobulin A 0.91 g/L; Immunoglobulin M 0.48 g/L; Hemoglobin 6.14 mmol/L; Leukocytes 14.5 ×10⁹/L; Absolute Neutrophil 8.78 ×10⁹/L; Platelets 269 ×10⁹/L; Creatinine 60.1 µmol/L; Blood Urea Nitrogen 1.43 mmol/L; Calcium 2.15 mmol/L; Albumin 34 g/L; Total Protein 5.6 g/dL; Glucose 11.2 mmol/L.
- Day 324 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.76 mg/dL; Immunoglobulin G 8.95 g/L; Immunoglobulin A 1.19 g/L; Immunoglobulin M 0.67 g/L; Lactate Dehydrogenase 3.1 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 3.87 ×10⁹/L; Platelets 219 ×10⁹/L; Creatinine 64.5 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.35 mmol/L; Albumin 44 g/L; Total Protein 7.4 g/dL; Glucose 9.63 mmol/L.
- Day 557: M Protein 0 g/dL; Hemoglobin 7.56 mmol/L; Leukocytes 6.4 ×10⁹/L; Platelets 204 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Glucose 17.1 mmol/L.
- Day 760: Hemoglobin 7.56 mmol/L; Leukocytes 6.1 ×10⁹/L; Platelets 143 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 5 mmol/L; Glucose 13.1 mmol/L.
- Day 816: Serum Free Immunoglobulin Light Chain, Kappa 24.7 mg/dL; Hemoglobin 7.25 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 128 ×10⁹/L; Creatinine 61.9 µmol/L.
- Day 872: Serum Free Immunoglobulin Light Chain, Kappa 25.8 mg/dL; Hemoglobin 7.69 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 140 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5.71 mmol/L.
- Day 935: Serum Free Immunoglobulin Light Chain, Kappa 28.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.43 mg/dL; Hemoglobin 7.19 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 120 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.13 mmol/L; Albumin 37 g/L; Total Protein 6.8 g/dL; Glucose 13.3 mmol/L.
- Day 1,075: Serum Free Immunoglobulin Light Chain, Kappa 37 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.19 mg/dL; Hemoglobin 6.94 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 136 ×10⁹/L; Creatinine 97.2 µmol/L.
- Day 1,152: Serum Free Immunoglobulin Light Chain, Kappa 46 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.21 mg/dL; Hemoglobin 6.57 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 145 ×10⁹/L; Creatinine 97.2 µmol/L.
- Day 1,215: Serum Free Immunoglobulin Light Chain, Kappa 44 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.22 mg/dL; Hemoglobin 6.82 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 154 ×10⁹/L; Creatinine 79.6 µmol/L; Glucose 9.96 mmol/L.
- Day 1,334: Hemoglobin 7.13 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 176 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.2 mmol/L; Glucose 10.7 mmol/L.
- Day 1,425: Serum Free Immunoglobulin Light Chain, Kappa 123 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.61 mg/dL; Immunoglobulin G 6.27 g/L; Immunoglobulin A 1.05 g/L; Immunoglobulin M 0.14 g/L; Hemoglobin 7.07 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 82 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.23 mmol/L; Albumin 38 g/L; Total Protein 6.8 g/dL; Glucose 10.8 mmol/L.
- Day 1,521: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 244 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.7 mg/dL; Immunoglobulin G 7.41 g/L; Immunoglobulin A 0.85 g/L; Immunoglobulin M 0.2 g/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.23 mmol/L; Albumin 38 g/L; Total Protein 6.8 g/dL; Glucose 10.8 mmol/L.
- Day 1,612: Serum Free Immunoglobulin Light Chain, Kappa 220 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.09 mg/dL; Hemoglobin 5.02 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 3.33 ×10⁹/L; Platelets 57 ×10⁹/L; Creatinine 48.6 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.28 mmol/L; Glucose 8.31 mmol/L.

Other clinical attributes
- Day -11: Weight: 96 kg; Height: 164 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1189_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -11 days.
- Sample MMRF_1189_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -11 days.
